Gene-level copy-number profile of tumor specimen TCGA-CV-A45Y-01A from TCGA case TCGA-CV-A45Y, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 61.4 years (22,442 days).
Specimen TCGA-CV-A45Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.1be61908-3359-4795-a912-75e8bb489fc1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A45Y-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c1542f0-3649-4097-973a-c82fd1fca6d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,600; copy number 2: 42,725; copy number 3: 5,874; copy number 4: 1,423; copy number 5: 1,868; copy number 6: 97; copy number 9: 119; copy number 11: 85; copy number 25: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A45Y-01A-11D-A253-01): tumor purity 0.5, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,193 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:154,334,943–183,163,839, 412 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:186,717,348–193,176,864, 89 genes, copy number 5 (broad region; genes not listed).
- chr8:82,033,533–82,961,926, 1 gene, copy number 5 (within-gene range 4–5): AC060765.2.
- chr8:82,514,568–88,328,025, 76 genes, copy number 5 (broad region; genes not listed).
- chr8:88,396,437–88,396,547, 1 gene, copy number 5: RNA5SP272.
- chr8:105,546,089–145,066,685, 584 genes, copy number 5 (broad region; genes not listed).
- chr12:67,131,567–72,728,844, 110 genes, copy number 5–25 (broad region; genes not listed).
- chr14:21,962,819–22,506,702, 75 genes, copy number 5 (broad region; genes not listed).
- chr22:19,479,457–22,619,163, 216 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr22:30,693,782–50,801,309, 629 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,219. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
